Somatic mutation profile of tumor specimen TCGA-4Z-AA7Q-01A (aliquot TCGA-4Z-AA7Q-01A-11D-A391-08) from TCGA case TCGA-4Z-AA7Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 79.3 years (28,981 days).
Specimen TCGA-4Z-AA7Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2e75219-33a9-4422-9b35-9b4e4a802171.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA7Q-10A (Blood Derived Normal), aliquot TCGA-4Z-AA7Q-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/393a3c05-404c-434e-94e9-e4232374b4c2

The open-access MAF lists 262 somatic variants for this specimen: 194 protein-altering or splice-affecting, 62 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 62, Nonsense Mutation 16, Intron 5, Splice Region 3, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 2, Nonstop Mutation 1, 3'Flank 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59206538, COSV59210925; called by muse, mutect2, varscan2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- AAMP | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV50306916; called by muse, mutect2
- ABCA12 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 58/149 reads (39%) | catalogued as COSV99788308, COSV99788845; called by muse, mutect2, varscan2
- ABCA3 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57049561, COSV57056989; called by muse, mutect2, varscan2
- AC093525.2 | c.1034G>C p.G345A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | PolyPhen benign (0.046); catalogued as COSV53549638, COSV53550148; called by muse, varscan2
- ADD3 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs759190548, COSV53320113; called by muse, mutect2, varscan2
- AGER | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66718714; called by muse, mutect2
- AHNAK | c.12310G>A p.D4104N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV57203705; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | catalogued as COSV51858678, COSV99782082; called by muse, mutect2
- ANKRD26 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1178839045, COSV65792836; called by muse, mutect2
- ARHGEF10 | c.2789A>G p.H930R (on ENST00000398564; = p.H905R on NM_014629.4) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV50642604; called by muse, mutect2
- ATF7IP | c.3794C>T p.S1265F | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV53766320, COSV53776761; called by muse, mutect2
- ATP6V0C | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1027015366, COSV53549642; called by muse, varscan2
- ATP7B | c.1286-1G>C p.X429_splice | Splice Site (SNP) | VAF 3/43 reads (7%) | catalogued as COSV54443904, COSV99666031; called by muse, mutect2
- ATP8A1 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52528784; called by muse, mutect2
- BCLAF1 | c.2255C>T p.S752L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV50356715; called by muse, mutect2
- BIRC6 | c.8648C>T p.S2883L | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV70195575, COSV70202360; called by muse, mutect2
- BTLA | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs370694951; called by muse, mutect2, varscan2
- C1QTNF7 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.999); catalogued as COSV54850327; called by muse, mutect2, varscan2
- C8orf76 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV52689864, COSV52692705; called by muse, mutect2, varscan2
- CACNA1A | c.4714G>C p.E1572Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV100803330, COSV64189761; called by muse, mutect2
- CCDC83 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54699787, COSV99721821; called by muse, mutect2, varscan2
- CDK15 | c.556G>A p.A186T (on ENST00000652192 / NM_001366386.2; = p.A135T on NM_139158.2) | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53631377; called by muse, mutect2, varscan2
- CDKL2 | c.795G>A p.K265= | Splice Region (SNP) | VAF 10/128 reads (8%) | catalogued as COSV56731957; called by muse, mutect2
- CFAP53 | c.186G>C p.L62F | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.96); catalogued as COSV68351309; called by muse, mutect2, varscan2
- CHD6 | c.4661A>C p.K1554T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64688418; called by muse, mutect2, varscan2
- CLCA1 | c.1976C>G p.S659* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99321906; called by muse, mutect2, varscan2
- CPSF6 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.981); catalogued as COSV57012225; called by muse, mutect2, varscan2
- CSNK1G1 | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57306796; called by muse, mutect2, varscan2
- DDB1 | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV100074305; called by muse, mutect2
- DDX1 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51838008; called by muse, mutect2
- DDX53 | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV60068486; called by muse, mutect2, varscan2
- DGKK | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV65706395; called by muse, mutect2, varscan2
- DHX30 | c.3123C>G p.F1041L (on ENST00000445061 / NM_138615.3; = p.F1002L on NM_014966.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.069); catalogued as COSV53135334; called by muse, mutect2, varscan2
- DIAPH2 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as COSV61260554; called by muse, mutect2, varscan2
- DIO3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as COSV100832173, COSV63773017; called by muse, mutect2, varscan2
- DMD | c.6580G>C p.E2194Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as COSV58891938; called by muse, mutect2, varscan2
- DMXL2 | c.6626C>T p.S2209L | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.977); catalogued as rs1200664389, COSV51840842; called by muse, mutect2, varscan2
- DNAAF2 | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as rs1320173552, COSV53567590; called by muse, mutect2, varscan2
- DNAH11 | c.10066G>C p.E3356Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as rs1299751052, COSV60940044; called by muse, mutect2
- DOCK9 | c.5524G>C p.E1842Q (on ENST00000376460 / NM_001366676.2; = p.E1843Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV59619854; called by muse, mutect2, varscan2
- DPYSL2 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60781901; called by muse, mutect2, varscan2
- DST | c.22235A>T p.Q7412L (on ENST00000361203 / NM_001374722.1; = p.Q5122L on NM_015548.5) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54997914; called by muse, mutect2, varscan2
- DZANK1 | c.763G>A p.E255K (on ENST00000262547 / NM_001099407.1; = p.E56K on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV52747480; called by muse, mutect2, varscan2
- EAF2 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV56545342, COSV99877372; called by muse, mutect2
- ECM2 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60739035; called by muse, mutect2, varscan2
- EPHB4 | c.1590G>C p.E530D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV62270181; called by muse, mutect2
- EVL | c.460G>C p.E154Q (on ENST00000402714 / NM_001330221.2; = p.E156Q on NM_016337.3) | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67374298, COSV67374616, COSV67375575; called by muse, mutect2
- EXPH5 | c.3263C>G p.S1088* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | catalogued as COSV99760930; called by muse, mutect2, varscan2
- EYA2 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57938541; called by muse, mutect2, varscan2
- FAM83G | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV58755289; called by muse, mutect2, varscan2
- FAT4 | c.4825G>A p.E1609K | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV67881460; called by muse, mutect2
- FHDC1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750200704, COSV52597533; called by mutect2, varscan2
- FLG2 | c.4920G>C p.Q1640H | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV66166665; called by muse, mutect2, varscan2
- FMN2 | c.2404C>T p.Q802* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as rs1053150067, COSV100142818; called by muse, mutect2
- FREM1 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66517869; called by muse, mutect2, varscan2
- FTHL17 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV63266294; called by muse, mutect2, varscan2
- GABRG2 | c.764G>A p.R255H (on ENST00000361925 / NM_001375343.1; = p.R215H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV62715550; called by muse, mutect2, varscan2
- GALNT15 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60215338; called by muse, mutect2, varscan2
- GATAD2A | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.563); catalogued as COSV53066699; called by muse, mutect2, varscan2
- GCC2 | c.3180G>A p.Q1060= | Splice Region (SNP) | VAF 16/64 reads (25%) | catalogued as COSV59174017, COSV59175466; called by muse, mutect2, varscan2
- GCN1 | c.6982G>T p.E2328* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100324664; called by muse, mutect2
- GDPD1 | c.847delinsAA p.E283Kfs*9 | Frame Shift Ins (INS) | VAF 18/107 reads (17%) | catalogued as COSV52380697; called by pindel, varscan2*
- GLIS3 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.275); catalogued as COSV60924047; called by muse, mutect2, varscan2
- GNA11 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as COSV50017451, COSV50021211; called by muse, mutect2, varscan2
- GRIA4 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as COSV56882288, COSV99031207; called by muse, mutect2, varscan2
- GSE1 | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as COSV99496054; called by muse, mutect2
- GSTA5 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV52861304; called by muse, mutect2, varscan2
- GTF2I | c.1309G>C p.E437Q (on ENST00000573035 / NM_032999.4; = p.E396Q on NM_001518.5) | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV60399219; called by muse, mutect2, varscan2
- H2AC20 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV58611291; called by muse, mutect2
- H2AZ2 | c.387G>C p.*129Yext*32 | Nonstop Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99760420; called by muse, mutect2, varscan2
- HEATR5B | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV51848973; called by muse, mutect2, varscan2
- HEATR6 | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51743703, COSV51744221; called by muse, mutect2
- HERC1 | c.11611C>T p.H3871Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV71245958; called by muse, mutect2, varscan2
- IGSF11 | c.247G>C p.D83H (on ENST00000393775 / NM_001015887.3; = p.D82H on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.82); catalogued as COSV100677014; called by muse, mutect2
- ITPR2 | c.5468C>G p.S1823* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV101189815; called by muse, mutect2, varscan2
- KBTBD8 | c.444C>A p.D148E | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV55126696; called by muse, mutect2, varscan2
- KCNH1 | c.2233C>T p.R745* (on ENST00000271751 / NM_172362.3; = p.R718* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as rs1385878367, COSV55099082; called by muse, mutect2, varscan2
- KDM6A | c.3644G>T p.G1215V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65037190, COSV65042194, COSV99060786; called by muse, mutect2, varscan2
- KIAA2026 | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV67353358; called by muse, mutect2, varscan2
- KIF25 | c.93G>T p.R31S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV63026493; called by muse, mutect2, varscan2
- KLHL1 | c.1811C>A p.S604* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100917010, COSV64775421; called by muse, mutect2
- KMT2D | c.12383C>T p.S4128L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs1368754155, COSV56411112; called by muse, mutect2, varscan2
- KMT2E | c.3041C>G p.P1014R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as rs769208829, COSV57569570; called by muse, mutect2, varscan2
- KRT20 | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV51423949; called by muse, mutect2
- KRT27 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV56971059; called by muse, mutect2
- LAMA3 | c.8153G>T p.G2718V (on ENST00000313654 / NM_198129.4; = p.G1109V on NM_000227.6) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52529003, COSV52529760; called by muse, mutect2, varscan2
- LBHD1 | c.587C>T p.S196F (on ENST00000431002 / NM_001367940.1; = p.S170F on NM_024099.3) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV63472637; called by muse, mutect2, varscan2
- LMOD3 | c.1404G>T p.M468I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV70455639; called by muse, mutect2, varscan2
- LMTK2 | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV51990536; called by muse, mutect2, varscan2
- LRFN3 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.935); catalogued as rs1259205451, COSV55816939, COSV99873648; called by muse, mutect2
- LRP1B | c.12797C>T p.S4266L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV67186926; called by muse, mutect2, varscan2
- LTB | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.04); catalogued as rs537728367, COSV53000366; called by muse, mutect2
- MADD | c.2747C>A p.S916Y | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60620453; called by muse, mutect2, varscan2
- MDP1 | c.485C>G p.T162S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs755822554, COSV51659479, COSV51660037; called by muse, mutect2, varscan2
- MEGF8 | c.344C>G p.S115* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99234465; called by muse, mutect2, varscan2
- MGAM | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV72073631; called by muse, mutect2
- MOV10 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV62490685; called by muse, mutect2, varscan2
- MYO16 | c.3020G>T p.R1007I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1312531228, COSV62745463; called by muse, mutect2, varscan2
- NACC1 | c.1368G>A p.M456I | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV52833928; called by muse, mutect2, varscan2
- NDST4 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52109110, COSV52113122; called by mutect2, varscan2
- NECTIN1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50598483; called by muse, mutect2
- NELFA | c.396G>C p.L132F (on ENST00000542778; = p.L121F on NM_005663.5) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV61605038; called by muse, mutect2, varscan2
- NFAT5 | c.4069C>G p.Q1357E | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV63025175; called by muse, mutect2, varscan2
- NLRC4 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.441); catalogued as COSV61591402; called by muse, mutect2
- NLRP9 | c.914C>G p.S305W | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as COSV60459687, COSV60463018, COSV60468327; called by muse, mutect2, varscan2
- NPAT | c.2326C>G p.P776A | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV53715961; called by muse, mutect2, varscan2
- NSF | c.1455G>C p.E485D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99833670; called by muse, mutect2, varscan2
- NUMA1 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs746813048, COSV100706350, COSV61183208; called by muse, mutect2, varscan2
- NUP107 | c.2272G>T p.E758* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as COSV57499980; called by muse, mutect2, varscan2
- OAS3 | c.1876C>G p.L626V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV57444077; called by muse, mutect2, varscan2
- OGT | c.2459G>C p.G820A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.983); catalogued as COSV65479475; called by muse, varscan2
- PADI1 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs372115327; called by muse, mutect2, varscan2
- PBRM1 | c.814-2A>G p.X272_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as rs1161522910, COSV56261313; called by muse, mutect2, varscan2
- PCDHGA3 | c.1176T>A p.F392L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53899324; called by muse, mutect2, varscan2
- PEX1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50394654; called by muse, mutect2, varscan2
- PLEC | c.10993G>A p.E3665K (on ENST00000322810 / NM_201380.4; = p.E3555K on NM_000445.5) | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV59604107; called by muse, mutect2
- POLG | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs1382145186, COSV51519850; called by muse, mutect2, varscan2
- POLR1E | c.565C>G p.Q189E (on ENST00000377792 / NM_001282766.1; = p.Q127E on NM_022490.4) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV66771520; called by muse, mutect2, varscan2
- PRDM15 | c.2035G>C p.D679H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.707); catalogued as rs749977245, COSV54148920; called by muse, mutect2, varscan2
- PRNP | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65173491; called by muse, mutect2, varscan2
- PRR27 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.659); catalogued as COSV60640134; called by muse, mutect2, varscan2
- PSD4 | c.2969C>G p.S990C | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV55524567; called by muse, mutect2, varscan2
- PTTG1IP | c.450G>C p.R150= | Splice Region (SNP) | VAF 16/69 reads (23%) | catalogued as COSV58365543; called by muse, mutect2, varscan2
- RAD51 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV51110984; called by muse, mutect2, varscan2
- RAPGEF1 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.34); catalogued as COSV64697725, COSV64699722; called by muse, mutect2, varscan2
- RASSF1 | c.504C>G p.I168M (on ENST00000357043 / NM_170714.2; = p.I164M on NM_007182.5) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51700044; called by muse, mutect2, varscan2
- RBM27 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); catalogued as COSV54587359; called by muse, mutect2
- REXO5 | c.882G>C p.Q294H | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54470707; called by muse, mutect2, varscan2
- RHBDL3 | c.761A>G p.Y254C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390197162, COSV52184598; called by muse, mutect2, varscan2
- RMDN1 | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.131); catalogued as rs1026914855, COSV52203516, COSV52204039; called by muse, mutect2, varscan2
- RNF10 | c.904G>T p.G302W | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100378684, COSV100378846, COSV58043509; called by muse, mutect2
- RNF220 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs541437323, COSV62404758; called by muse, mutect2, varscan2
- RNF220 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV59189763; called by muse, mutect2
- RPGR | c.29-1G>C p.X10_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV58832509; called by muse, mutect2, varscan2
- RRP12 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100212893; called by muse, mutect2
- RYR3 | c.6784G>A p.G2262R | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV63109436; called by muse, mutect2, varscan2
- SAMD9 | c.3307C>G p.L1103V | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs746799013, COSV101180353, COSV66073005; called by muse, mutect2, varscan2
- SIGLEC7 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs533294268, COSV58314460, COSV58314697; called by muse, mutect2, varscan2
- SIRT1 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53017080, COSV99281986; called by muse, mutect2, varscan2
- SLC17A5 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63287028; called by muse, mutect2, varscan2
- SLC19A2 | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV52546241; called by muse, mutect2
- SLC36A3 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs769669460, COSV58855555; called by muse, mutect2, varscan2
- SLC5A9 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV52581989; called by muse, mutect2
- SPAG1 | c.660C>G p.F220L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52557964; called by muse, mutect2
- SPICE1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV55622056; called by muse, mutect2
- SPPL2C | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV61291819; called by muse, mutect2, varscan2
- ST8SIA2 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV51567470, COSV99184363; called by muse, mutect2
- SYK | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV65325211; called by muse, mutect2
- SYTL3 | c.1718G>C p.G573A (on ENST00000611299 / NM_001242394.1; = p.G505A on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99791537; called by muse, mutect2
- TARBP1 | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50178403; called by muse, mutect2, varscan2
- TASOR2 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs760417967, COSV60165498; called by muse, varscan2
- TET1 | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV101017607; called by muse, mutect2
- TET1 | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV101017609; called by muse, mutect2, varscan2
- TFAP2A | c.1066C>G p.Q356E (on ENST00000482890; = p.Q348E on NM_001032280.3) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60230948; called by muse, mutect2, varscan2
- THADA | c.4804G>C p.E1602Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV57675990; called by muse, mutect2, varscan2
- TLN1 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as COSV59204111; called by muse, mutect2, varscan2
- TOP1MT | c.304C>G p.H102D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61316367; called by muse, mutect2
- TP63 | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV53196522, COSV53212854; called by muse, mutect2
- TRAF3IP3 | c.879G>C p.E293D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.149); catalogued as COSV50550499, COSV50551875; called by muse, mutect2
- TRIM24 | c.2341G>A p.D781N (on ENST00000343526 / NM_015905.3; = p.D747N on NM_003852.4) | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as COSV58969015; called by muse, mutect2, varscan2
- TRIM39 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV64954905; called by muse, mutect2, varscan2
- TSEN34 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55474304; called by muse, mutect2, varscan2
- UAP1 | c.958C>G p.R320G | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54849056; called by muse, mutect2
- UBR2 | c.4811C>T p.P1604L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV65748763; called by muse, mutect2
- USHBP1 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV53102260; called by muse, mutect2, varscan2
- USP34 | c.10372G>C p.D3458H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV63724425; called by muse, mutect2, varscan2
- USP34 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV68398142; called by muse, mutect2
- USP35 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV71572604, COSV71573344; called by mutect2, varscan2
- USP54 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV60439706; called by muse, mutect2
- USP8 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56162244; called by muse, mutect2, varscan2
- USPL1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV54998552; called by muse, mutect2, varscan2
- VPS13C | c.11035C>T p.P3679S (on ENST00000644861 / NM_020821.3; = p.P3636S on NM_017684.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV51121828; called by muse, mutect2, varscan2
- VPS4B | c.758G>C p.R253T | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53068465; called by muse, mutect2, varscan2
- WDTC1 | c.891G>C p.L297F | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV100089518, COSV60087137; called by muse, mutect2
- ZFP91 | c.1690G>C p.D564H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV60157180; called by muse, mutect2, varscan2
- ZNF28 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60421784; called by muse, mutect2, varscan2
- ZNF345 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as COSV59322686; called by muse, mutect2, varscan2
- ZNF486 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV58717440, COSV58720277; called by muse, mutect2, varscan2
- ZNF570 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 8/133 reads (6%) | catalogued as COSV100356021; called by muse, mutect2
- ZNF667 | c.1302G>C p.Q434H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1216654034, COSV52631237; called by muse, mutect2, varscan2
- ZNF681 | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV101267397, COSV68075523; called by muse, mutect2
- ZNF750 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.376); catalogued as rs34566230, COSV99489799; called by muse, mutect2
- ZNF92 | c.760G>C p.E254Q (on ENST00000328747 / NM_152626.4; = p.E185Q on NM_007139.4) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV100165669, COSV60873032; called by muse, mutect2, varscan2
- ZSCAN10 | c.1163G>A p.R388H (on ENST00000252463; = p.R443H on NM_032805.3) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs1411725527, COSV99373826; called by muse, varscan2
- CXorf38 | c.7_9dup p.L3dup | In Frame Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- ERBB3 | c.1778_1783del p.V593_L594del | In Frame Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- IGKV3-15 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MGAT4A | c.547_550del p.D183Mfs*6 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel, varscan2
- PMPCA | c.1525_1528dup p.L510Rfs*5 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel
- TRAJ1 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- TSPEAR | c.407_420del p.D136Vfs*116 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, varscan2
- ZFYVE16 | c.4483G>C p.E1495Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.155); called by muse, mutect2
- ABRAXAS1 | c.258G>A p.K86= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV58948112, COSV58950163; called by muse, mutect2
- ADAMTS17 | c.1434C>T p.I478= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1224628836, COSV51473216; called by muse, mutect2, varscan2
- AHNAK2 | c.12378G>A p.V4126= | Silent (SNP) | VAF 110/432 reads (25%) | catalogued as COSV60907961; called by muse, mutect2, varscan2
- AMFR | c.1623C>G p.L541= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV51919832; called by muse, mutect2, varscan2
- AMN | c.60C>T p.V20= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV54486081; called by muse, mutect2, varscan2
- ANKMY1 | c.2295G>T p.L765= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV56030132; called by muse, mutect2, varscan2
- ARHGAP45 | c.1869G>C p.S623= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV57429281, COSV57434787; called by muse, mutect2
- ARNTL | c.933C>A p.L311= (on ENST00000403290 / NM_001297719.2; = p.L310= on NM_001178.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV62985199; called by muse, mutect2, varscan2
- BRS3 | c.423C>A p.L141= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV65710673; called by muse, mutect2, varscan2
- CCDC138 | c.1306C>T p.L436= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV54564286; called by muse, mutect2
- CHD5 | c.5505C>T p.L1835= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs575620025, COSV99312493; called by muse, mutect2
- CRB1 | c.1614A>G p.L538= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV66328683; called by muse, mutect2, varscan2
- CYP4A22 | c.1179C>T p.L393= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1435685142, COSV53738094; called by muse, mutect2, varscan2
- DHRS7B | c.453C>A p.I151= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV60887335; called by muse, mutect2, varscan2
- DPP7 | c.1131C>A p.L377= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV65370934; called by muse, mutect2
- FKBP14 | c.27C>G p.V9= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV51648550; called by muse, mutect2, varscan2
- FLT1 | c.3039G>C p.L1013= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV56717922; called by muse, mutect2, varscan2
- FNDC3B | c.549A>C p.R183= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV61037437; called by muse, mutect2, varscan2
- FSD1 | c.408G>A p.A136= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs752988066, COSV55694577; called by muse, mutect2, varscan2
- FXYD5 | c.30C>T p.L10= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs17850535, COSV54342084; called by muse, mutect2, varscan2
- GAB4 | c.282C>A p.I94= | Silent (SNP) | VAF 25/192 reads (13%) | catalogued as COSV68752978; called by muse, mutect2, varscan2
- GABRA6 | c.96C>G p.V32= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV50877620; called by muse, mutect2, varscan2
- GREB1 | c.1743G>A p.A581= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs369400404, COSV99303923; called by muse, mutect2, varscan2
- H2BC7 | c.222C>A p.I74= | Silent (SNP) | VAF 17/170 reads (10%) | catalogued as COSV61911556; called by muse, mutect2
- HCN3 | c.1401C>T p.F467= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as rs1470602995, COSV61360397; called by muse, mutect2
- HOXD4 | c.750G>A p.T250= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs777306654, COSV60459308; called by muse, mutect2, varscan2
- HSPG2 | c.7431C>T p.L2477= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as rs768049269, COSV65968989; called by muse, mutect2, varscan2
- IGHV3-20 | c.15G>C p.L5= | Silent (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.240C>T p.F80= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs566659731, COSV101534359; called by muse, mutect2, varscan2
- KCNH5 | c.171C>T p.D57= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs368773009; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF20B | c.177C>G p.L59= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV53302293; called by muse, mutect2
- LACC1 | c.522G>C p.L174= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV57828604; called by muse, mutect2, varscan2
- MAGEB6 | c.141T>A p.A47= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV66871834; called by muse, mutect2, varscan2
- MDC1 | c.3018C>G p.L1006= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV64523270; called by muse, mutect2
- MTMR8 | c.2114G>A p.*705= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100878271; called by muse, mutect2, varscan2
- NEB | c.8784G>A p.L2928= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs1366039360, COSV50811227; called by muse, mutect2, varscan2
- NKIRAS2 | c.291G>T p.V97= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV56917392; called by muse, mutect2, varscan2
- NOL11 | c.45G>C p.L15= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV53522681; called by muse, mutect2
- OPN5 | c.195G>A p.L65= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV55244210; called by muse, mutect2
- OR6C3 | c.69G>A p.V23= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV65570612; called by muse, mutect2, varscan2
- P3H2 | c.1116G>C p.V372= | Silent (SNP) | VAF 23/191 reads (12%) | catalogued as COSV60018399; called by muse, mutect2, varscan2
- PIAS4 | c.1296C>G p.L432= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV53678228; called by muse, mutect2, varscan2
- PIK3CD | c.171G>T p.P57= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs373365253; called by muse, mutect2, varscan2
- PKD1L1 | c.4896G>A p.V1632= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV56958041; called by muse, mutect2
- PLEKHH1 | c.1776G>C p.V592= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV61280267; called by muse, mutect2, varscan2
- SASS6 | c.42G>C p.V14= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV54926386; called by muse, mutect2, varscan2
- SCAI | c.576C>G p.L192= (on ENST00000336505 / NM_001144877.3; = p.L215= on NM_173690.5) | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV60609962; called by muse, mutect2, varscan2
- SENP7 | c.417T>C p.S139= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as COSV58607843; called by muse, mutect2, varscan2
- SLITRK1 | c.1203C>T p.L401= | Silent (SNP) | VAF 26/173 reads (15%) | catalogued as rs550166518, COSV65674263; called by muse, mutect2, varscan2
- ST8SIA3 | c.897G>A p.L299= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV60653331; called by muse, mutect2, varscan2
- STAM2 | c.141A>G p.L47= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs1251011686, COSV55729703; called by muse, mutect2, varscan2
- TAS2R20 | c.576G>C p.L192= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV67852272; called by muse, mutect2, varscan2
- THRA | c.1173G>T p.G391= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV52840725, COSV52846927; called by muse, mutect2, varscan2
- TNPO1 | c.2571C>G p.L857= | Silent (SNP) | VAF 23/162 reads (14%) | catalogued as COSV61520218; called by muse, mutect2, varscan2
- TNRC6A | c.4524C>T p.F1508= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100169438; called by muse, mutect2
- TPRA1 | c.144C>G p.L48= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs138504527; called by muse, mutect2, varscan2
- TSEN2 | c.972G>A p.T324= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs775135022, COSV53187630; called by muse, mutect2
- TUBGCP4 | c.1797G>A p.Q599= (on ENST00000260383 / NM_001286414.3; = p.Q598= on NM_014444.5) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV53017698; called by muse, mutect2, varscan2
- USP1 | c.1515C>T p.F505= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV60573707; called by muse, mutect2, varscan2
- USP54 | c.2757C>T p.A919= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV60439692; called by muse, mutect2, varscan2
- VAPB | c.30C>G p.L10= | Silent (SNP) | VAF 2/9 reads (22%) | called by muse, mutect2
- ZNRF3 | c.855C>T p.L285= (on ENST00000544604 / NM_001206998.2; = p.L185= on NM_032173.3) | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as COSV60431321; called by muse, mutect2
- AP4S1 | c.306+12C>G | Intron (SNP) | VAF 6/71 reads (8%) | catalogued as COSV53554339; called by muse, mutect2
- CARS1 | c.26-5508G>A | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as COSV53450086; called by muse, mutect2, varscan2
- CDK20 | c.76-37G>C | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs753833398, COSV57481712; called by muse, mutect2
- CEP295 | chr11:93735152 G>C | 3'Flank (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- DBNDD1 | c.32-553G>T | Intron (SNP) | VAF 9/65 reads (14%) | catalogued as COSV50021824; called by muse, mutect2, varscan2
- DEPDC5 | c.1870+2296C>G | Intron (SNP) | VAF 7/110 reads (6%) | catalogued as COSV56691106; called by muse, mutect2
